Somatic mutation profile of tumor specimen TCGA-AG-3906-01A (aliquot TCGA-AG-3906-01A-01W-1073-09) from TCGA case TCGA-AG-3906, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 67.9 years (24,806 days).
Specimen TCGA-AG-3906-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d87087f-0fa9-4d6a-ac7d-b253f3e2f64d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3906-10A (Blood Derived Normal), aliquot TCGA-AG-3906-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45db025f-90d2-4cdc-98e0-969e21e29c82

The open-access MAF lists 563 somatic variants for this specimen: 432 protein-altering or splice-affecting, 120 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 351, Silent 120, Frame Shift Ins 49, Nonsense Mutation 12, Frame Shift Del 9, Splice Site 5, Intron 4, RNA 4, Splice Region 3, Nonstop Mutation 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 48/164 reads (29%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 63/211 reads (30%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- SCN2A | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 105/322 reads (33%) | catalogued as rs181327458, COSV51836300, COSV51838393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 49/114 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5875C>A p.L1959I | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV70027494; called by muse, mutect2, varscan2
- ABCA5 | c.4090T>C p.S1364P | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67016435; called by muse, mutect2, varscan2
- ABCD4 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as COSV100084368; called by muse, mutect2, varscan2
- ACAN | c.4999G>A p.V1667M | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1260878311, COSV61359286; called by muse, mutect2
- ACAN | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV61359305; called by muse, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 52/140 reads (37%) | catalogued as rs757016425; called by mutect2, varscan2
- ACTL7A | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100453163; called by muse, mutect2, varscan2
- ACTR8 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452684482, COSV51635281; called by muse, mutect2, varscan2
- ACVR1B | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765649298, COSV57774835; called by muse, varscan2
- ADAMTS10 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); catalogued as rs962019378, COSV54353807; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2846C>A p.S949Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV54998786; called by muse, mutect2, varscan2
- ADPRHL1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs151314929; called by muse, mutect2, varscan2
- AGBL1 | c.1903T>G p.F635V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101223551; called by muse, mutect2, varscan2
- AGBL2 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100101821; called by muse, mutect2, varscan2
- AIFM2 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57160811; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 44/146 reads (30%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALG10 | c.438dup p.N147* | Frame Shift Ins (INS) | VAF 106/292 reads (36%) | catalogued as rs1163730964; called by mutect2, varscan2
- ALS2 | c.4489A>G p.N1497D | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV99969557; called by muse, mutect2, varscan2
- ANK1 | c.5572C>T p.P1858S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99224200; called by muse, mutect2, varscan2
- ANKMY2 | c.69T>G p.G23= | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100187162; called by mutect2, varscan2
- AP1S2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100236798; called by muse, mutect2, varscan2
- APC | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 63/153 reads (41%) | catalogued as rs1314843920, CM013690, COSV57335557; called by muse, mutect2, varscan2
- APC | c.4245del p.S1415Rfs*4 | Frame Shift Del (DEL) | VAF 71/245 reads (29%) | catalogued as COSV57334974; called by mutect2, pindel, varscan2
- APOB | c.8204A>C p.D2735A | Missense Mutation (SNP) | VAF 164/473 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV99266414; called by muse, mutect2, varscan2
- AQP2 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV99550864; called by muse, mutect2, varscan2
- ARHGAP26 | c.1289C>G p.P430R | Missense Mutation (SNP) | VAF 99/455 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.894); catalogued as COSV99191141, COSV99191624; called by muse, mutect2, varscan2
- ARL13A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773610188, COSV65880170; called by muse, mutect2, varscan2
- ARMCX5 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 112/1044 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99863439; called by muse, mutect2
- ASTN2 | c.3229G>T p.E1077* (on ENST00000313400 / NM_001365069.1; = p.E1026* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 111/329 reads (34%) | catalogued as COSV99941010; called by muse, mutect2, varscan2
- ATG4C | c.1318dup p.S440Ffs*4 | Frame Shift Ins (INS) | VAF 30/115 reads (26%) | catalogued as rs35696652; called by mutect2, pindel, varscan2
- ATG9A | c.2388G>T p.R796S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99521994; called by muse, mutect2
- ATM | c.3154G>C p.A1052P | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV99590350; called by muse, mutect2
- ATP4A | c.119A>T p.K40M | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99382784; called by muse, mutect2, varscan2
- ATP6V1H | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748113513, COSV62217954; called by muse, mutect2, varscan2
- AURKC | c.269G>T p.R90L (on ENST00000302804 / NM_001015878.2; = p.R56L on NM_003160.3) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV57137647, COSV57137869; called by muse, mutect2, varscan2
- B3GALT4 | c.725dup p.R243Qfs*108 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- B3GNT2 | c.924del p.F309Sfs*9 | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | catalogued as rs1300549233; called by mutect2, pindel, varscan2
- BCL2L1 | c.611G>A p.R204Q (on ENST00000307677 / NM_001317919.2; = p.R141Q on NM_001191.4) | Missense Mutation (SNP) | VAF 128/166 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as rs1568844220, COSV100304763; called by muse, mutect2, varscan2
- BCR | c.2807A>G p.D936G | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100006686; called by muse, mutect2
- BMP2K | c.1904T>C p.L635S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58594389; called by muse, mutect2, varscan2
- BRPF3 | c.1855A>G p.N619D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs766376496, COSV100325981; called by muse, mutect2, varscan2
- BTBD16 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs769336919, COSV99584985; called by muse, mutect2, varscan2
- C11orf42 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99792217; called by muse, mutect2, varscan2
- C9 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54676176; called by muse, mutect2
- CABIN1 | c.329T>C p.M110T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs991344007, COSV99573527; called by muse, mutect2, varscan2
- CACNG4 | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs1567761503, COSV100047707; called by muse, mutect2, varscan2
- CCDC80 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489458675, COSV52814970; called by muse, mutect2, varscan2
- CCDC80 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV99244970; called by muse, mutect2, varscan2
- CCKBR | c.1037G>T p.W346L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58100661; called by muse, mutect2, varscan2
- CD163L1 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100550291; called by muse, mutect2, varscan2
- CD22 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV50058171, COSV99323414; called by muse, mutect2, varscan2
- CD40 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs371997367; called by muse, mutect2, varscan2
- CD53 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602279; called by muse, mutect2, varscan2
- CDH12 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs765635488, COSV66386124; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1193T>C p.I398T (on ENST00000357886 / NM_001365728.1; = p.I384T on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100212187; called by muse, mutect2, varscan2
- CEACAM16 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs769206320, COSV101312712; called by muse, mutect2, varscan2
- CEACAM5 | c.1948A>G p.N650D | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV99704012; called by muse, mutect2, varscan2
- CEP126 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567302421, COSV54826947; called by muse, mutect2, varscan2
- CEP95 | c.2194A>G p.M732V | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV73609006; called by muse, mutect2, varscan2
- CERT1 | c.1269G>A p.M423I (on ENST00000405807 / NM_001130105.1; = p.M295I on NM_005713.3) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV54661239, COSV99783447; called by muse, mutect2, varscan2
- CFAP43 | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99530837; called by muse, mutect2, varscan2
- CFDP1 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99382758; called by muse, mutect2, varscan2
- CHEK1 | c.426T>A p.D142E | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV99629745; called by muse, mutect2, varscan2
- CHML | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs911830187, COSV59362859; called by muse, mutect2, varscan2
- COL17A1 | c.2262A>G p.R754= | Splice Region (SNP) | VAF 64/162 reads (40%) | catalogued as COSV100793229; called by muse, mutect2, varscan2
- COL19A1 | c.3429A>C p.*1143Cext*49 | Nonstop Mutation (SNP) | VAF 58/179 reads (32%) | catalogued as COSV100506691; called by muse, mutect2, varscan2
- COL21A1 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 37/128 reads (29%) | catalogued as rs377112827, COSV55159886; called by muse, mutect2, varscan2
- COL4A1 | c.4441C>T p.R1481W | Missense Mutation (SNP) | VAF 44/1004 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199586038, COSV65424330; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- COQ8A | c.1769T>C p.L590P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62009330; called by muse, mutect2, varscan2
- CPEB2 | c.2553A>C p.K851N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV99470445; called by muse, mutect2, varscan2
- CRB1 | c.2104T>C p.Y702H | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100957949; called by muse, mutect2, varscan2
- CRIM1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99753759; called by muse, mutect2, varscan2
- CSMD2 | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV99585401, COSV99591931; called by muse, mutect2
- CUL9 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as rs760068503, COSV52727808; called by muse, mutect2, varscan2
- CYLD | c.2471T>C p.V824A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100282571; called by muse, mutect2, varscan2
- CYP2A13 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV57837253; called by muse, mutect2, varscan2
- DCUN1D4 | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 39/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100584578; called by muse, mutect2, varscan2
- DDR1 | c.625T>C p.Y209H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100241757; called by muse, mutect2, varscan2
- DDX60L | c.4126G>C p.V1376L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as COSV52712083; called by muse, mutect2
- DGKA | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV100093207; called by muse, mutect2, varscan2
- DIAPH2 | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1342982771, COSV100233601; called by muse, mutect2, varscan2
- DISC1 | c.2255G>T p.W752L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV100790220; called by muse, mutect2, varscan2
- DLG5 | c.4004T>C p.L1335P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100967617; called by muse, varscan2
- DMD | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 142/198 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774139970, COSV55866059; called by muse, mutect2, varscan2
- DMXL2 | c.3812A>T p.Y1271F | Missense Mutation (SNP) | VAF 138/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99196596; called by muse, mutect2, varscan2
- DNAH10 | c.6017C>T p.P2006L (on ENST00000409039; = p.P1945L on NM_207437.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68991921; called by muse, mutect2, varscan2
- DNAH10 | c.6120G>T p.K2040N (on ENST00000409039; = p.K1979N on NM_207437.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68991924; called by muse, mutect2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH2 | c.11426T>C p.I3809T | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV101209474; called by muse, mutect2, varscan2
- DNAJC19 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100700337; called by muse, mutect2
- DOCK10 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV51378423; called by muse, mutect2, varscan2
- DOCK2 | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99913481; called by muse, mutect2
- DOCK3 | c.2485A>G p.M829V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs769251462, COSV56515964; called by muse, varscan2
- DPY19L4 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.992); catalogued as COSV68962691; called by muse, mutect2, varscan2
- DUSP3 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1380319519, COSV56825154; called by muse, mutect2, varscan2
- ECI2 | c.952A>G p.T318A (on ENST00000380118 / NM_206836.3; = p.T288A on NM_006117.2) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100326591; called by muse, mutect2, varscan2
- ECSIT | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs150413743; called by muse, mutect2, varscan2
- EFCAB3 | c.672A>T p.E224D | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100540311; called by muse, mutect2, varscan2
- EHD1 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100277149; called by muse, mutect2, varscan2
- EHF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669623; called by muse, mutect2, varscan2
- ELAVL1 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60966687; called by muse, mutect2, varscan2
- ENDOD1 | c.1087T>C p.C363R | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53589289; called by muse, varscan2
- EPHB6 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100844350; called by muse, mutect2, varscan2
- EPN3 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370636443; called by muse, mutect2, varscan2
- ERBB4 | c.3481G>T p.E1161* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as COSV61481080, COSV61490983; called by muse, mutect2, varscan2
- FANCA | c.3694T>G p.F1232V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV99235093; called by muse, mutect2, varscan2
- FAT2 | c.9490G>A p.A3164T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as rs200687536, COSV55822526; called by muse, mutect2, varscan2
- FBXO24 | c.1033C>A p.L345M (on ENST00000241071 / NM_033506.3; = p.L383M on NM_012172.5) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV53825310; called by muse, mutect2
- FBXO47 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100960765; called by muse, mutect2, varscan2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FCHSD2 | c.1856T>C p.F619S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238686; called by muse, mutect2, varscan2
- FGFR4 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs147846257; called by muse, mutect2, varscan2
- FIGLA | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100189745; called by muse, mutect2, varscan2
- FN1 | c.1187A>G p.Q396R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV100117464; called by muse, mutect2, varscan2
- FNBP1L | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53092836; called by muse, mutect2, varscan2
- FREM2 | c.6578-1G>T p.X2193_splice | Splice Site (SNP) | VAF 14/190 reads (7%) | catalogued as COSV99749372; called by muse, mutect2
- FRMD4B | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68329580; called by muse, mutect2, varscan2
- FSHR | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs372147824; called by muse, mutect2, varscan2
- GAB1 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763452007, COSV99528510; called by muse, mutect2, varscan2
- GALNT12 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs774534357, COSV66662552; called by muse, mutect2, varscan2
- GALNT5 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 94/318 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755395227, COSV99375344; called by muse, mutect2, varscan2
- GANAB | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1190900041, COSV99642080; called by muse, mutect2, varscan2
- GAPVD1 | c.2218A>G p.S740G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99783405; called by muse, mutect2, varscan2
- GAS2L1 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53330640; called by muse, mutect2, varscan2
- GCNT2 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101097523; called by muse, mutect2, varscan2
- GEMIN5 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV99594090; called by muse, mutect2, varscan2
- GMIP | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747541980, COSV52555591; called by muse, mutect2, varscan2
- GPD2 | c.1927A>C p.I643L | Missense Mutation (SNP) | VAF 95/308 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV100133387; called by muse, mutect2, varscan2
- GPR174 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52132131, COSV52134926; called by muse, mutect2, varscan2
- GPR32 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs762217628, COSV54513645; called by muse, mutect2, varscan2
- GRINA | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100507346; called by muse, mutect2, varscan2
- GSTCD | c.1897A>G p.I633V (on ENST00000360505 / NM_001031720.3; = p.I546V on NM_024751.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs758690077, COSV64733036; called by muse, mutect2
- GTF3C1 | c.5541dup p.E1848Rfs*22 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs763161381; called by mutect2, varscan2
- H1-5 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV58899746; called by muse, mutect2, varscan2
- HAPLN1 | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57147073; called by muse, mutect2, varscan2
- HCN4 | c.1979-1G>C p.X660_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99983918; called by muse, mutect2
- HDAC6 | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100490998; called by muse, mutect2
- HGF | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs765830204, COSV99737567; called by muse, mutect2, varscan2
- HIF1A | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100049037; called by muse, mutect2, varscan2
- HMCN1 | c.12293T>A p.L4098* | Nonsense Mutation (SNP) | VAF 44/147 reads (30%) | catalogued as COSV99631387; called by muse, mutect2, varscan2
- HOXB13 | c.601+2T>C p.X201_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as rs1423895179, COSV99285259; ClinVar: uncertain significance; called by muse, mutect2
- HSPA8 | c.1547A>G p.E516G | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV57083632; called by muse, mutect2
- HTT | c.5860A>G p.I1954V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as COSV100750957; called by muse, mutect2
- IDE | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99794123; called by muse, mutect2, varscan2
- IDH3B | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 190/738 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs368124689; called by muse, mutect2, varscan2
- IFIT1B | c.1394G>T p.R465M | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100879086; called by muse, mutect2, varscan2
- IGHD6-19 | c.1G>C p.G1R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs537818120; called by muse, mutect2, varscan2
- IGLV3-27 | c.147dup p.Y50Ifs*19 | Frame Shift Ins (INS) | VAF 28/88 reads (32%) | catalogued as rs751481735; called by mutect2, varscan2
- IGSF9B | c.1260dup p.Y421Lfs*60 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs775604395; called by mutect2, varscan2
- IL13RA2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99683187; called by muse, mutect2, varscan2
- IL1R1 | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99292698; called by muse, mutect2, varscan2
- INPP4B | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99525291; called by muse, mutect2, varscan2
- ITGA6 | c.2734T>C p.S912P (on ENST00000442250; = p.S873P on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.522); catalogued as COSV99905681; called by muse, mutect2, varscan2
- ITGAE | c.3158A>G p.H1053R | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV53992907; called by muse, mutect2, varscan2
- ITM2A | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100964471; called by muse, mutect2, varscan2
- JAK1 | c.3191T>C p.V1064A | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99605385; called by muse, mutect2, varscan2
- JAM2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV57256026; called by muse, mutect2, varscan2
- JCAD | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV100948452; called by muse, mutect2, varscan2
- JCHAIN | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs1476727026, COSV99636495; called by muse, mutect2, varscan2
- JMJD1C | c.5561T>C p.F1854S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550671; called by muse, mutect2, varscan2
- KATNB1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369064313; called by muse, mutect2
- KATNIP | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV99851451; called by muse, mutect2, varscan2
- KCNC4 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV100873647; called by muse, mutect2, varscan2
- KCNH1 | c.1496C>T p.T499M (on ENST00000271751 / NM_172362.3; = p.T472M on NM_002238.4) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs942768469, COSV55092957; called by muse, mutect2, varscan2
- KHDRBS2 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99835000; called by muse, mutect2, varscan2
- KIAA1755 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV99642293; called by muse, mutect2, varscan2
- KLHL26 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs1284743885, COSV56317350; called by muse, mutect2, varscan2
- KMT2B | c.4768G>A p.A1590T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.541); catalogued as COSV99719953; called by muse, mutect2
- KMT2D | c.15322C>T p.R5108C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174064870, COSV56430353; called by muse, mutect2, varscan2
- KMT2D | c.14956C>T p.R4986C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765693458, COSV56430366; called by muse, mutect2, varscan2
- KPNA5 | c.1562A>T p.N521I | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV62651825; called by muse, varscan2
- KRT10 | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54089362; called by muse, mutect2, varscan2
- KRTAP5-6 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV101191765; called by muse, mutect2, varscan2
- LGI2 | c.1618A>T p.I540F | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV101180880; called by muse, mutect2, varscan2
- LIMK2 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258591161, COSV100058654; called by muse, mutect2, varscan2
- LINGO2 | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV58059086; called by muse, mutect2, varscan2
- LNPK | c.1138A>G p.I380V | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs748231677, COSV99770281; called by muse, mutect2, varscan2
- LRIG3 | c.1684T>C p.Y562H | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57867352; called by muse, mutect2, varscan2
- LRP12 | c.1351dup p.C451Lfs*9 | Frame Shift Ins (INS) | VAF 34/105 reads (32%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP1B | c.6164A>T p.Y2055F | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101257971, COSV67252990; called by muse, mutect2, varscan2
- LRP1B | c.3905T>C p.L1302P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67218308; called by muse, mutect2
- LRP2 | c.7186A>G p.N2396D | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99789267; called by muse, mutect2, varscan2
- LRRC4C | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53433021, COSV53436497; called by muse, mutect2, varscan2
- MAN2B1 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418139; called by muse, mutect2
- MEGF10 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.097); catalogued as rs150095036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEOX1 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100233756; called by muse, mutect2, varscan2
- METTL7A | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1430599653, COSV59840663; called by muse, mutect2, varscan2
- MIA | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as COSV99648252; called by muse, mutect2
- MIER1 | c.379G>A p.E127K (on ENST00000355356 / NM_001077701.3; = p.E144K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV100591187, COSV62529899; called by muse, mutect2, varscan2
- MIPEP | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101193166; called by muse, mutect2, varscan2
- MLF1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV63033279; called by muse, mutect2, varscan2
- MPP3 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as COSV101263347; called by muse, mutect2, varscan2
- MTBP | c.183A>C p.E61D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV100012292; called by muse, mutect2
- MTUS2 | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 12/238 reads (5%) | catalogued as COSV70916304; called by muse, mutect2
- MYCBP2 | c.13830A>C p.E4610D (on ENST00000357337; = p.E4648D on NM_015057.5) | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV62015935; called by muse, mutect2, varscan2
- MYCBP2 | c.1828G>T p.G610* (on ENST00000357337; = p.G648* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 27/318 reads (8%) | catalogued as COSV62015940; called by muse, mutect2
- MYO5C | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV55905086; called by muse, mutect2, varscan2
- MYOF | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 202/693 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1218388444, COSV63703006; called by muse, mutect2, varscan2
- NAALADL2 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV70794722; called by muse, mutect2, varscan2
- NAPA | c.592_594del p.L198del | In Frame Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs893080790; called by pindel, varscan2
- NCKAP5 | c.3227T>C p.L1076P | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV58439135; called by muse, mutect2, varscan2
- NDC1 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 132/404 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99323732; called by muse, mutect2
- NKG7 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389909; called by muse, mutect2, varscan2
- NOP56 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV100250002; called by muse, mutect2, varscan2
- NPFFR2 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs750555908, COSV100440936; called by muse, mutect2
- NPY5R | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100642837; called by muse, mutect2, varscan2
- NUBPL | c.423T>C p.C141= | Splice Region (SNP) | VAF 80/240 reads (33%) | catalogued as COSV99809897; called by muse, mutect2, varscan2
- NUDCD1 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53456259; called by muse, mutect2, varscan2
- NUMA1 | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769545751, COSV100706332; called by muse, mutect2, varscan2
- NXPE3 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs781572583, COSV56289327; called by muse, mutect2, varscan2
- OBSL1 | c.3562G>A p.G1188R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs770388002, COSV54705226; called by muse, mutect2, varscan2
- OGT | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 180/272 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65480466; called by muse, mutect2, varscan2
- OLFM1 | c.857C>T p.T286M (on ENST00000371793 / NM_001282611.2; = p.T268M on NM_014279.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs372599021; called by muse, mutect2, varscan2
- OPN1LW | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs376687141, COSV64064163; called by muse, mutect2, varscan2
- OR10A5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.555); catalogued as rs754779185, COSV100203514; called by muse, mutect2
- OR1Q1 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99939276; called by muse, mutect2
- OR51B5 | c.94A>G p.M32V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1272360390, COSV100332588; called by muse, mutect2, varscan2
- OR56A4 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV58109834, COSV58111717; called by muse, mutect2, varscan2
- OR6C3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs1418803351, COSV65570984; called by muse, mutect2, varscan2
- OR8D1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs139899466, COSV63442502; called by muse, mutect2, varscan2
- OR9G4 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100265183; called by muse, mutect2, varscan2
- OSBPL7 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs368457499; called by muse, mutect2, varscan2
- OSBPL9 | c.1136T>C p.L379S | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100543685; called by muse, mutect2, varscan2
- OXA1L | c.1198A>G p.T400A (on ENST00000285848; = p.T340A on NM_005015.5) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs193921091, COSV53536378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P2RY6 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201497467, COSV62935755; called by muse, mutect2, varscan2
- PABPC5 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 86/122 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs772523316, COSV57040186, COSV57043239; called by muse, mutect2, varscan2
- PAPLN | c.2300C>T p.A767V (on ENST00000554301; = p.A740V on NM_173462.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.359); catalogued as COSV99389951; called by muse, mutect2, varscan2
- PARD3B | c.1460T>A p.L487H | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV100594128; called by muse, mutect2, varscan2
- PATZ1 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as COSV99315426; called by muse, mutect2
- PCDH17 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV100931753; called by muse, mutect2, varscan2
- PCDH18 | c.2569A>G p.S857G | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as COSV100787398; called by muse, mutect2
- PCDHA10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs782304851, COSV56492965; called by muse, mutect2, varscan2
- PCDHA5 | c.1273A>T p.T425S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100972387; called by muse, mutect2, varscan2
- PCDHB12 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs1554286668, COSV99507478; called by muse, mutect2, varscan2
- PCDHB16 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99502308; called by muse, mutect2, varscan2
- PCDHGC3 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV52752258; called by muse, mutect2, varscan2
- PDS5B | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.763); catalogued as COSV59726102; called by muse, mutect2, varscan2
- PDZD2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99225615; called by muse, mutect2
- PDZD9 | c.647T>C p.V216A (on ENST00000424898 / NM_001363519.1; = p.V156A on NM_173806.4) | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs1287261358, COSV99193355; called by muse, mutect2
- PGK1 | c.1093A>G p.R365G | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100540711; called by muse, mutect2
- PHF10 | c.555A>T p.Q185H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100199962; called by muse, mutect2, varscan2
- PI4KA | c.2624dup p.P876Sfs*36 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs747391554; called by mutect2, pindel, varscan2
- PLAGL2 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99867372; called by muse, mutect2, varscan2
- PLB1 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as COSV59823274; called by muse, mutect2
- PLCD1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99379003; called by muse, mutect2
- PLCXD2 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as COSV67339435; called by muse, mutect2, varscan2
- PLS1 | c.865A>G p.S289G | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100538182; called by muse, mutect2, varscan2
- PNMA1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99679029; called by muse, mutect2, varscan2
- PNPLA5 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs749917334, COSV99336671; called by muse, mutect2, varscan2
- POC1B | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544325; called by muse, mutect2, varscan2
- POLR1A | c.4071G>T p.K1357N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs774764516, COSV99806958, COSV99807976; called by muse, mutect2, varscan2
- POLR3C | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100492977; called by muse, mutect2, varscan2
- PPP6R3 | c.799A>C p.S267R | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99676832; called by muse, mutect2, varscan2
- PRDM1 | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1296446700, COSV100958884; called by muse, mutect2
- PRICKLE3 | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as COSV100889926; called by muse, mutect2, varscan2
- PRNP | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11538758, CM930598, COSV65173628; called by muse, mutect2, varscan2
- PRPF40B | c.2554A>T p.S852C (on ENST00000380281; = p.S839C on NM_012272.3) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV99526575; called by muse, mutect2
- PRRT2 | c.607C>G p.P203A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV54883018, COSV99569683; called by muse, varscan2
- PSD2 | c.780T>G p.D260E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99217290; called by muse, mutect2, varscan2
- PSME2 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.914); catalogued as COSV99395642; called by muse, mutect2, varscan2
- PSME4 | c.4673A>G p.E1558G | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV101122556; called by muse, mutect2, varscan2
- RAB3GAP2 | c.4182A>G p.*1394Wext*11 | Nonstop Mutation (SNP) | VAF 65/197 reads (33%) | catalogued as COSV100228416; called by muse, mutect2, varscan2
- RANBP6 | c.1772T>C p.L591P | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99424236; called by muse, mutect2, varscan2
- RAPGEF1 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100940651; called by muse, mutect2
- RBFOX1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100302189; called by muse, varscan2
- RCC1 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV100868149; called by muse, mutect2, varscan2
- RERG | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 178/546 reads (33%) | catalogued as rs773343591, COSV99917427; called by muse, mutect2, varscan2
- REV1 | c.3110A>C p.D1037A | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV99177395; called by muse, mutect2, varscan2
- RGL1 | c.347+2T>C p.X116_splice (on ENST00000360851 / NM_001297672.2; = p.X151_splice on NM_015149.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/232 reads (4%) | catalogued as COSV100487092; called by muse, mutect2
- RIMS1 | c.4361A>G p.Q1454R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV99328075; called by muse, mutect2, varscan2
- ROR1 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100935367; called by muse, mutect2, varscan2
- RPS6KA2 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs766805003, COSV55816627; called by muse, mutect2, varscan2
- RRM1 | c.755T>A p.V252E | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV56163914; called by muse, mutect2, varscan2
- RSC1A1 | c.1253A>C p.Q418P | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100197704; called by muse, mutect2, varscan2
- RXFP2 | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100034411; called by muse, mutect2, varscan2
- RYR2 | c.12671A>G p.E4224G | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV100771485; called by muse, mutect2
- RYR2 | c.13387A>G p.R4463G | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV100771486; called by muse, mutect2, varscan2
- SBNO1 | c.2331G>A p.W777* (on ENST00000420886; = p.W776* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 51/172 reads (30%) | catalogued as COSV99929357; called by muse, mutect2, varscan2
- SBSPON | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV52076236; called by muse, mutect2, varscan2
- SCN7A | c.741dup p.L248Sfs*19 | Frame Shift Ins (INS) | VAF 41/138 reads (30%) | catalogued as rs769551067; called by mutect2, pindel, varscan2
- SEC24B | c.3269G>A p.G1090D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV54498482; called by muse, mutect2, varscan2
- SECISBP2 | c.1936A>G p.T646A | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100368752; called by muse, mutect2, varscan2
- SEL1L | c.1871A>G p.Q624R | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377990; called by muse, mutect2, varscan2
- SEL1L3 | c.2027T>C p.V676A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53539664; called by muse, mutect2, varscan2
- SELP | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740324; called by muse, mutect2, varscan2
- SEMA3A | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.934); catalogued as rs762612767, COSV54863349; called by muse, mutect2, varscan2
- SEPTIN8 | c.449T>A p.I150N | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99736384; called by muse, mutect2, varscan2
- SERPINE2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769638840, COSV51455837; called by muse, mutect2, varscan2
- SGK2 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1388897484, COSV100414710; called by muse, mutect2, varscan2
- SGK2 | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100414712; called by muse, mutect2, varscan2
- SH3BP5L | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748728779, COSV100822028; called by muse, mutect2, varscan2
- SIAE | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99704002, COSV99704063; called by muse, mutect2
- SIPA1L2 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53388691; called by muse, mutect2, varscan2
- SLC16A10 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100920910; called by muse, mutect2
- SLC26A4 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV99707207; called by muse, mutect2, varscan2
- SLC43A3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201915801, COSV61449811; called by muse, mutect2, varscan2
- SLC6A12 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100675153; called by muse, mutect2, varscan2
- SLC9B1 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99599772; called by muse, mutect2, varscan2
- SLC9C2 | c.597dup p.G200Wfs*14 | Frame Shift Ins (INS) | VAF 51/153 reads (33%) | catalogued as rs760633653; called by mutect2, varscan2
- SLITRK5 | c.1259A>C p.Y420S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100280934; called by muse, mutect2, varscan2
- SMARCAL1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs529024384, COSV61919905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCB1 | c.839A>G p.Y280C (on ENST00000263121; = p.Y326C on NM_003073.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV99575526; called by muse, mutect2, varscan2
- SMARCD2 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99856515; called by muse, mutect2, varscan2
- SNRNP70 | c.470T>G p.M157R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99672362; called by muse, mutect2, varscan2
- SNX19 | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99773255; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 71/221 reads (32%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SP100 | c.1164A>T p.L388F | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.102); catalogued as COSV99893571; called by muse, mutect2, varscan2
- SPART | c.1976A>G p.K659R | Missense Mutation (SNP) | VAF 493/1030 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100768791; called by muse, mutect2, varscan2
- SPATA2L | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs746584672, COSV57049490; called by muse, mutect2, varscan2
- SPP1 | c.432A>T p.E144D (on ENST00000395080 / NM_001040058.2; = p.E130D on NM_000582.2) | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV99421118; called by muse, mutect2, varscan2
- SPRTN | c.663dup p.G222Rfs*18 | Frame Shift Ins (INS) | VAF 48/142 reads (34%) | catalogued as rs752960031; called by mutect2, varscan2
- SPRY1 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762280661, COSV100201861; called by muse, mutect2, varscan2
- SPTBN2 | c.5147T>C p.V1716A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100019817; called by muse, mutect2, varscan2
- SRD5A1 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV99944174; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs750306056; called by mutect2, varscan2
- ST3GAL1 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | PolyPhen probably damaging (0.96); catalogued as COSV100172242; called by muse, mutect2, varscan2
- ST8SIA3 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 46/99 reads (46%) | PolyPhen benign (0.121); catalogued as COSV100129590; called by muse, mutect2, varscan2
- ST8SIA4 | c.29T>C p.I10T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | PolyPhen benign (0.015); catalogued as COSV51508987; called by muse, mutect2, varscan2
- STAG3 | c.337-2A>G p.X113_splice | Splice Site (SNP) | VAF 128/382 reads (34%) | catalogued as rs1296715259, COSV100426054; called by muse, mutect2, varscan2
- STARD3NL | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV99151596; called by muse, mutect2, varscan2
- STAU2 | c.314T>C p.M105T (on ENST00000524300 / NM_001164380.2; = p.M73T on NM_014393.2) | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100869137; called by muse, mutect2, varscan2
- STK33 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs936275480, COSV59397545; called by muse, mutect2, varscan2
- STX8 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs752149374, COSV60487682; called by muse, mutect2, varscan2
- STXBP4 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 132/248 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.384); catalogued as COSV54840723; called by muse, mutect2, varscan2
- STYK1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV99312004; called by muse, mutect2
- SUN3 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 299/797 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV52049993; called by muse, mutect2, varscan2
- SUN3 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV52050000; called by muse, mutect2, varscan2
- SVEP1 | c.8791T>C p.C2931R | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929318; called by muse, mutect2, varscan2
- SYCP2L | c.1367G>C p.R456P | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); catalogued as COSV51652299; called by muse, mutect2, varscan2
- SYNE1 | c.17176G>A p.A5726T (on ENST00000367255 / NM_182961.4; = p.A5655T on NM_033071.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.329); catalogued as rs775685010, COSV54999627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.15433G>C p.G5145R | Missense Mutation (SNP) | VAF 95/332 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100648025; called by muse, mutect2, varscan2
- SYT13 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.12); catalogued as COSV99194747; called by muse, mutect2, varscan2
- TEP1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV99402716; called by muse, mutect2
- TET3 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99996446; called by muse, mutect2
- TGDS | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54300527, COSV99725238; called by muse, mutect2
- TGOLN2 | c.1037T>G p.M346R | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV56405816, COSV56405832; called by muse, mutect2, varscan2
- TIMELESS | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs763159822, COSV57510718; called by muse, mutect2
- TMEM100 | c.296dup p.L99Ffs*91 | Frame Shift Ins (INS) | VAF 69/317 reads (22%) | catalogued as rs894486999; called by mutect2, varscan2
- TMEM117 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs746604616, COSV99863001; called by muse, mutect2, varscan2
- TMEM170A | c.427A>C p.T143P | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100713247; called by muse, mutect2, varscan2
- TMEM38B | c.286dup p.C96Lfs*4 | Frame Shift Ins (INS) | VAF 27/88 reads (31%) | catalogued as rs756048916; called by mutect2, varscan2
- TMPO | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99702099; called by muse, mutect2
- TMTC1 | c.1638G>T p.Q546H (on ENST00000539277 / NM_001193451.2; = p.Q438H on NM_175861.3) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99760124; called by muse, mutect2
- TNK2 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as COSV100361468; called by muse, mutect2, varscan2
- TNN | c.2459T>C p.V820A | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV99512319; called by muse, mutect2, varscan2
- TNRC6A | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100170215; called by muse, mutect2, varscan2
- TOP3B | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs756829071, COSV100592592; called by muse, mutect2, varscan2
- TRAM1L1 | c.1033dup p.R345Kfs*13 | Frame Shift Ins (INS) | VAF 43/261 reads (16%) | catalogued as rs1237787070; called by mutect2, varscan2
- TRIM32 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100528623; called by muse, mutect2, varscan2
- TRIM58 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100825176; called by muse, mutect2, varscan2
- TRIP11 | c.2338A>G p.K780E | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV50917930; called by muse, mutect2, varscan2
- TSHZ2 | c.2470G>T p.D824Y | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100296339, COSV61592348; called by muse, mutect2, varscan2
- TTN | c.86419C>T p.R28807C (on ENST00000591111; = p.R21383C on NM_003319.4) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | PolyPhen possibly damaging (0.681); catalogued as rs756030714, COSV59867380, COSV60466098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB8 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs1554738305, COSV59115429; called by muse, mutect2, varscan2
- TUBD1 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100360172; called by muse, mutect2
- TXLNA | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.236); catalogued as rs746456840, COSV65313873; called by muse, mutect2, varscan2
- UGT2A2 | c.279T>A p.D93E | Missense Mutation (SNP) | VAF 128/397 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99684571, COSV99684853; called by muse, mutect2, varscan2
- UMPS | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99229143; called by muse, mutect2
- VTN | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99879730; called by muse, mutect2, varscan2
- VWA8 | c.3007T>C p.F1003L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV99864477; called by muse, mutect2, varscan2
- WBP11 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 144/433 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV99660769; called by muse, mutect2, varscan2
- WDFY2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs150232196; called by muse, mutect2, varscan2
- WDR17 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99707851; called by muse, mutect2, varscan2
- WNT2 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253004521, COSV55409855; called by muse, mutect2, varscan2
- WRN | c.3128T>C p.L1043P | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99989364; called by muse, mutect2
- WWC2 | c.3085A>T p.K1029* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67857310; called by muse, mutect2, varscan2
- WWP1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.393); catalogued as COSV99616679; called by muse, mutect2, varscan2
- XPO1 | c.2357T>C p.I786T | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.153); catalogued as COSV101294244; called by muse, mutect2
- XRCC6 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1362550653, COSV100777857; called by muse, mutect2, varscan2
- XRCC6 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100777860; called by muse, mutect2, varscan2
- ZBED9 | c.3739C>A p.P1247T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.042); catalogued as COSV101509303, COSV71729777; called by muse, mutect2, varscan2
- ZBTB11 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs367718842, COSV100465579; called by muse, mutect2, varscan2
- ZC3H6 | c.1096A>G p.T366A | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59667222; called by muse, mutect2, varscan2
- ZNF154 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV70744927; called by muse, mutect2, varscan2
- ZNF208 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as rs757937575, COSV68103971; called by muse, varscan2
- ZNF366 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1461997166, COSV59215012; called by muse, mutect2, varscan2
- ZNF429 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs895767576, COSV61915729; called by muse, mutect2, varscan2
- ZNF470 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57968546; called by muse, mutect2, varscan2
- ZNF585A | c.835T>C p.F279L (on ENST00000292841 / NM_001288800.2; = p.F224L on NM_152655.3) | Missense Mutation (SNP) | VAF 209/598 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99492878, COSV99493298; called by muse, mutect2, varscan2
- ZNF585B | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as rs777925506, COSV57215177; called by muse, mutect2, varscan2
- ZNF609 | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100441332; called by muse, mutect2, varscan2
- ZNF623 | c.1048A>G p.N350D | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as COSV101513573; called by muse, mutect2
- ZNF749 | c.2212A>G p.T738A | Missense Mutation (SNP) | VAF 174/532 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775393686, COSV61945830; called by mutect2, varscan2
- ZNF765 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67182360; called by muse, mutect2
- ZNF85 | c.1598C>A p.T533N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV60213343, COSV60214269; called by muse, mutect2
- ZSWIM2 | c.1861A>G p.S621G | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99720323; called by muse, mutect2, varscan2
- ZSWIM4 | c.1204T>C p.C402R | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99585076; called by muse, mutect2, varscan2
- ZWINT | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV100571533; called by muse, mutect2, varscan2
- ACBD5 | c.204G>T p.M68I (on ENST00000375888 / NM_001352568.1; = p.M70I on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BPTF | c.3259dup p.I1087Nfs*6 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | called by mutect2, varscan2
- C17orf80 | c.1045dup p.E349Gfs*25 | Frame Shift Ins (INS) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- CADM2 | c.788dup p.D264Gfs*9 (on ENST00000407528 / NM_001167674.2; = p.D266Gfs*9 on NM_153184.4) | Frame Shift Ins (INS) | VAF 86/250 reads (34%) | called by mutect2, pindel, varscan2
- CCDC178 | c.2154dup p.D719Rfs*3 (on ENST00000383096 / NM_001105528.3; = p.D681Rfs*3 on NM_198995.3) | Frame Shift Ins (INS) | VAF 35/71 reads (49%) | called by mutect2, pindel, varscan2
- CEP350 | c.8251dup p.I2751Nfs*29 | Frame Shift Ins (INS) | VAF 64/200 reads (32%) | called by mutect2, varscan2
- CHD5 | c.1060dup p.E354Gfs*35 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | called by mutect2, pindel, varscan2
- COG6 | c.192dup p.V65Cfs*2 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- CYP2C8 | c.1089dup p.T364Hfs*10 | Frame Shift Ins (INS) | VAF 68/255 reads (27%) | called by mutect2, pindel, varscan2
- DMD | c.798dup p.Q267Sfs*21 | Frame Shift Ins (INS) | VAF 69/235 reads (29%) | called by mutect2, pindel, varscan2
- DNAJC12 | c.327dup p.D110Rfs*8 | Frame Shift Ins (INS) | VAF 76/250 reads (30%) | called by mutect2, pindel, varscan2
- EP300 | c.1649_1650dup p.P551Cfs*51 | Frame Shift Ins (INS) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- EPB41L5 | c.186dup p.A63Sfs*8 | Frame Shift Ins (INS) | VAF 55/213 reads (26%) | called by mutect2, pindel, varscan2
- FATE1 | c.166dup p.Q56Pfs*58 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | called by pindel, varscan2
- HAUS8 | c.408dup p.K137Efs*8 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- HDAC9 | c.2622G>C p.W874C | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-49 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INHA | c.562_563dup p.L189Cfs*2 | Frame Shift Ins (INS) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- INTS13 | c.1899dup p.P634Tfs*4 | Frame Shift Ins (INS) | VAF 52/206 reads (25%) | called by mutect2, pindel, varscan2
- ITGAE | c.266dup p.R91Efs*37 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- LIN28B | c.312dup p.S105Efs*7 | Frame Shift Ins (INS) | VAF 137/479 reads (29%) | called by mutect2, pindel, varscan2
- LYSMD3 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | called by pindel, varscan2
- NCOR1 | c.1584dup p.E529Rfs*7 | Frame Shift Ins (INS) | VAF 31/58 reads (53%) | called by mutect2, varscan2
- NPL | c.677dup p.T227Dfs*9 | Frame Shift Ins (INS) | VAF 33/99 reads (33%) | called by mutect2, varscan2
- OR5H1 | c.488dup p.L163Ffs*8 | Frame Shift Ins (INS) | VAF 60/283 reads (21%) | called by mutect2, pindel, varscan2
- PPP5C | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.461); called by mutect2, varscan2
- PPRC1 | c.1783dup p.T595Nfs*14 | Frame Shift Ins (INS) | VAF 49/188 reads (26%) | called by mutect2, pindel, varscan2
- RALGAPA2 | c.456dup p.A153Cfs*28 | Frame Shift Ins (INS) | VAF 33/141 reads (23%) | called by mutect2, pindel, varscan2
- RBM15 | c.1769dup p.P591Tfs*23 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D31 | c.2960del p.N987Ifs*25 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | called by mutect2, pindel, varscan2
- TBCCD1 | c.988dup p.A330Gfs*25 | Frame Shift Ins (INS) | VAF 51/166 reads (31%) | called by mutect2, pindel, varscan2
- TIMM23 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, varscan2
- TRAP1 | c.1296dup p.D433Rfs*3 | Frame Shift Ins (INS) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- TRPC7 | c.316dup p.V106Gfs*73 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- TULP3 | c.657dup p.T220Hfs*20 | Frame Shift Ins (INS) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- UBE4B | c.3231_3232dup p.Q1078Lfs*45 (on ENST00000343090 / NM_001105562.3; = p.Q949Lfs*45 on NM_006048.5) | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- WDHD1 | c.3346dup p.S1116Ffs*12 | Frame Shift Ins (INS) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- ZNF331 | c.182del p.N61Tfs*5 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- ZNF426 | c.833dup p.P279Afs*5 | Frame Shift Ins (INS) | VAF 75/340 reads (22%) | called by mutect2, pindel, varscan2
- ZNF518B | c.1230del p.N411Mfs*6 | Frame Shift Del (DEL) | VAF 57/269 reads (21%) | called by mutect2, pindel, varscan2
- AADAC | c.771T>C p.D257= | Silent (SNP) | VAF 15/246 reads (6%) | catalogued as rs756745068, COSV99233339; called by muse, mutect2
- ABCA12 | c.1197G>T p.L399= (on ENST00000272895 / NM_173076.3; = p.L81= on NM_015657.3) | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99790703; called by muse, mutect2, varscan2
- ABCD3 | c.852G>A p.G284= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as COSV100238984; called by muse, mutect2, varscan2
- ABLIM1 | c.957A>C p.T319= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as COSV99522286; called by muse, mutect2, varscan2
- ACAN | c.5256G>A p.V1752= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV61359297, COSV61366226; called by muse, varscan2
- ACSS1 | c.1227C>A p.S409= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100053850, COSV60221479; called by muse, mutect2, varscan2
- ADGRE1 | c.543T>C p.A181= | Silent (SNP) | VAF 192/678 reads (28%) | catalogued as COSV99165452; called by muse, mutect2, varscan2
- ADGRV1 | c.12141T>A p.L4047= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV101316155; called by muse, mutect2, varscan2
- AGFG2 | c.1338G>T p.G446= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99499399; called by muse, mutect2, varscan2
- AIM2 | c.321T>C p.S107= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs773309029, COSV100931095; called by muse, mutect2, varscan2
- AKAP9 | c.2991A>G p.L997= | Silent (SNP) | VAF 80/231 reads (35%) | catalogued as COSV100662585; called by muse, mutect2, varscan2
- AL645922.1 | c.3378T>C p.P1126= | Silent (SNP) | VAF 57/150 reads (38%) | catalogued as COSV100963962; called by muse, mutect2, varscan2
- ARHGEF12 | c.3018T>C p.N1006= | Silent (SNP) | VAF 18/350 reads (5%) | catalogued as COSV63103948; called by muse, mutect2
- ARL14 | c.306A>G p.R102= | Silent (SNP) | VAF 83/288 reads (29%) | catalogued as COSV100296504; called by muse, mutect2, varscan2
- ATF7 | c.9C>T p.D3= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs377276777; called by mutect2, varscan2
- BIRC6 | c.5424T>C p.T1808= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs1265180862, COSV70198197; called by muse, mutect2, varscan2
- BRCA2 | c.1050A>G p.E350= | Silent (SNP) | VAF 16/415 reads (4%) | catalogued as COSV101204428; called by muse, mutect2
- CACNA1G | c.732T>C p.P244= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs766932544, COSV61724861; ClinVar: likely benign; called by mutect2, varscan2
- CACNA1S | c.5349T>C p.A1783= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100755151; called by muse, mutect2, varscan2
- CAVIN1 | c.987C>T p.R329= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs754999996, COSV63812280; called by muse, mutect2, varscan2
- CCDC186 | c.1797T>C p.N599= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as COSV65161847; called by muse, mutect2, varscan2
- CCL16 | c.204C>G p.V68= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- CDC20 | c.1185C>T p.A395= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs368218162, COSV100196509; called by muse, mutect2
- CDK5RAP2 | c.1474T>C p.L492= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- CKMT2 | c.633C>T p.S211= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs140162798; called by muse, mutect2
- CLEC4F | c.1014G>A p.L338= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV99713824; called by muse, mutect2, varscan2
- CMYA5 | c.8127T>C p.P2709= | Silent (SNP) | VAF 134/350 reads (38%) | catalogued as COSV71405394; called by muse, mutect2, varscan2
- COPB2 | c.759A>G p.V253= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as COSV100300719; called by muse, mutect2, varscan2
- CTC1 | c.258G>A p.S86= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as rs369789111, COSV100236559; called by muse, mutect2, varscan2
- DAPK1 | c.4044G>A p.G1348= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs951197099, COSV100802249; called by muse, mutect2, varscan2
- DHDDS | c.105G>T p.G35= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV52575148, COSV99360536; called by muse, mutect2
- DHX57 | c.1107T>C p.A369= | Silent (SNP) | VAF 14/288 reads (5%) | catalogued as COSV99769672; called by muse, mutect2
- DNAH5 | c.6115C>T p.L2039= | Silent (SNP) | VAF 100/259 reads (39%) | catalogued as COSV99451323; called by muse, mutect2, varscan2
- DTNB | c.33C>T p.T11= | Silent (SNP) | VAF 106/373 reads (28%) | catalogued as COSV56473075; called by muse, mutect2, varscan2
- EGF | c.1332T>C p.N444= | Silent (SNP) | VAF 125/325 reads (38%) | catalogued as rs774632401, COSV54478302; called by muse, mutect2, varscan2
- ELOA | c.1428A>G p.S476= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as COSV69310004; called by muse, mutect2, varscan2
- EML4 | c.111A>G p.E37= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100580968; called by muse, mutect2, varscan2
- EXTL3 | c.1746G>A p.P582= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1426115254, COSV99594130; called by muse, mutect2, varscan2
- FATE1 | c.171A>G p.K57= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as COSV64849021; called by muse, varscan2
- FOXP2 | c.621A>G p.Q207= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1018656357, COSV100646925; called by muse, mutect2
- GJC1 | c.1068C>T p.Y356= | Silent (SNP) | VAF 50/212 reads (24%) | catalogued as rs770353465, COSV100395201; called by muse, mutect2, varscan2
- GLMN | c.996C>A p.I332= | Silent (SNP) | VAF 71/249 reads (29%) | catalogued as COSV100950097; called by muse, mutect2, varscan2
- GRIK4 | c.504A>G p.K168= | Silent (SNP) | VAF 192/467 reads (41%) | catalogued as COSV101483646; called by muse, mutect2, varscan2
- GSPT1 | c.171C>T p.I57= (on ENST00000420576 / NM_001130007.2; = p.I195= on NM_002094.4) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101341717; called by muse, mutect2
- GTDC1 | c.780T>C p.G260= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV53993168; called by muse, mutect2, varscan2
- GTF2B | c.795A>C p.S265= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100980549; called by muse, mutect2, varscan2
- GTPBP8 | c.597C>T p.S199= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs771944735, COSV55606988; called by muse, mutect2, varscan2
- HDAC1 | c.1122G>A p.P374= | Silent (SNP) | VAF 65/165 reads (39%) | catalogued as rs767557241, COSV61482048; called by muse, mutect2, varscan2
- HNF1A | c.1092T>C p.S364= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV57461404; called by muse, mutect2, varscan2
- HNRNPLL | c.429T>C p.A143= | Silent (SNP) | VAF 16/215 reads (7%) | catalogued as COSV99696603; called by muse, mutect2
- HTR2C | c.630C>T p.N210= | Silent (SNP) | VAF 80/244 reads (33%) | catalogued as rs782644122, COSV52222042; called by muse, mutect2, varscan2
- HTRA4 | c.1332T>C p.T444= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100205811; called by muse, mutect2, varscan2
- JKAMP | c.94C>T p.L32= (on ENST00000554271 / NM_001284201.1; = p.L18= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs891477701, COSV54199138; called by muse, mutect2, varscan2
- JUP | c.1209T>C p.D403= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100159658; called by muse, mutect2, varscan2
- KAT6B | c.5241C>T p.S1747= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs1363271666, COSV99768398; called by muse, mutect2, varscan2
- LAMB2 | c.780C>T p.L260= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1560076637, COSV59731233; called by muse, mutect2, varscan2
- MCM6 | c.1125C>T p.G375= | Silent (SNP) | VAF 76/200 reads (38%) | catalogued as rs767725842, COSV51469640; called by muse, mutect2, varscan2
- MED13 | c.2739A>G p.G913= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as COSV101181165; called by muse, mutect2, varscan2
- MUC16 | c.17970A>G p.S5990= | Silent (SNP) | VAF 122/362 reads (34%) | catalogued as COSV67488148; called by muse, mutect2, varscan2
- MYO9B | c.699G>A p.Q233= | Silent (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- NCOA2 | c.642T>A p.G214= | Silent (SNP) | VAF 13/444 reads (3%) | catalogued as COSV101476016; called by muse, mutect2
- NLRP5 | c.1956G>A p.L652= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV66763818; called by muse, mutect2, varscan2
- OR10H3 | c.435T>C p.L145= | Silent (SNP) | VAF 118/374 reads (32%) | catalogued as rs1267779144, COSV100008439; called by muse, mutect2, varscan2
- OR11H1 | c.453G>C p.L151= | Silent (SNP) | VAF 84/267 reads (31%) | catalogued as COSV99421870; called by muse, mutect2, varscan2
- OR4S2 | c.454T>C p.L152= | Silent (SNP) | VAF 144/451 reads (32%) | catalogued as rs1250426748, COSV56747426, COSV56747580; called by muse, mutect2, varscan2
- PCDHA1 | c.2025G>A p.A675= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs143057294; called by muse, mutect2, varscan2
- PCDHA4 | c.1887C>T p.G629= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV63543087; called by muse, mutect2, varscan2
- PCDHB1 | c.828G>A p.A276= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100128435, COSV60629538; called by muse, mutect2, varscan2
- PCDHB10 | c.1491C>T p.H497= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV53377894; called by muse, mutect2, varscan2
- PCDHGA2 | c.606C>T p.R202= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs1173613101, COSV53931403; called by muse, mutect2, varscan2
- PCDHGA9 | c.1965G>A p.S655= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs750464541, COSV99541415; called by muse, mutect2, varscan2
- PCYOX1L | c.507G>A p.S169= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs763606512, COSV51003315, COSV99199218; called by muse, mutect2, varscan2
- PDCD4 | c.1362T>C p.R454= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as COSV99701058; called by muse, mutect2
- PDGFRA | c.1218T>C p.T406= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99957020; called by muse, mutect2, varscan2
- PEF1 | c.384A>G p.S128= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1557585104, COSV101035922; called by muse, mutect2, varscan2
- PHKB | c.1039A>C p.R347= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV100067777; called by muse, mutect2, varscan2
- PIKFYVE | c.3570T>C p.G1190= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100011011; called by muse, mutect2, varscan2
- PLCZ1 | c.324T>C p.A108= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99856561; called by muse, mutect2, varscan2
- PLXNB1 | c.1827C>T p.S609= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1445702349, COSV99603050; called by muse, mutect2
- RAB4B | c.192G>T p.T64= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV54571613, COSV99648254; called by muse, mutect2, varscan2
- RAG1 | c.486T>C p.D162= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs753042511, COSV100201005; called by muse, mutect2, varscan2
- RAPGEF1 | c.2286G>A p.L762= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100940652; called by muse, mutect2
- RFX5 | c.1272A>C p.G424= | Silent (SNP) | VAF 71/287 reads (25%) | catalogued as COSV100923900; called by muse, mutect2, varscan2
- RGS12 | c.1707C>T p.C569= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1034425271, COSV100375895; called by muse, mutect2, varscan2
- RNF145 | c.1578G>A p.T526= (on ENST00000424310 / NM_001199383.2; = p.T554= on NM_144726.2) | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as rs780679803, COSV50866303; called by muse, mutect2, varscan2
- RNF40 | c.270A>G p.T90= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100222187; called by muse, mutect2, varscan2
- SAG | c.423A>G p.Q141= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101300685; called by muse, mutect2
- SCEL | c.1410A>G p.E470= (on ENST00000349847 / NM_144777.3; = p.E450= on NM_003843.4) | Silent (SNP) | VAF 36/452 reads (8%) | catalogued as COSV100583038; called by muse, mutect2
- SIPA1L1 | c.636T>C p.I212= | Silent (SNP) | VAF 129/372 reads (35%) | catalogued as COSV100665702; called by muse, mutect2, varscan2
- SKIL | c.1017T>C p.P339= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV99378376; called by muse, mutect2, varscan2
- SMARCC2 | c.2373C>T p.S791= | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as rs1213608018, COSV57217167; called by muse, mutect2, varscan2
- SP110 | c.1521A>G p.K507= | Silent (SNP) | VAF 248/600 reads (41%) | catalogued as COSV51249212; called by muse, varscan2
- STEAP1 | c.807A>G p.A269= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as rs1173442226, COSV99787693; called by muse, mutect2
- SUZ12 | c.1098T>C p.N366= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV59499413; called by muse, mutect2, varscan2
- SVIL | c.543A>G p.E181= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV100881378; called by muse, mutect2, varscan2
- TAFA4 | c.405T>C p.T135= | Silent (SNP) | VAF 20/489 reads (4%) | catalogued as COSV99807308; called by muse, mutect2
- TAX1BP1 | c.939C>T p.S313= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs572441406, COSV99604578; called by muse, mutect2
- THOC1 | c.105T>C p.S35= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99863490; called by muse, mutect2, varscan2
- TIAM1 | c.2865C>T p.L955= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs765735636, COSV99736473; called by muse, mutect2
- TMEM109 | c.333A>G p.G111= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV50004221; called by muse, mutect2, varscan2
- TMEM236 | c.723C>T p.S241= | Silent (SNP) | VAF 126/405 reads (31%) | called by muse, varscan2
- TNFRSF19 | c.723A>G p.S241= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99947500; called by muse, mutect2, varscan2
- TRARG1 | c.267C>T p.I89= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs777449339, COSV61562707; called by muse, mutect2, varscan2
- TTLL7 | c.477G>C p.V159= | Silent (SNP) | VAF 69/243 reads (28%) | catalogued as COSV99552602; called by muse, mutect2, varscan2
- TTYH2 | c.558A>G p.S186= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99483096; called by muse, mutect2, varscan2
- UBQLN3 | c.1221C>A p.S407= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100293787; called by muse, mutect2, varscan2
- UGT1A8 | c.369T>C p.H123= | Silent (SNP) | VAF 193/572 reads (34%) | catalogued as COSV65076758; called by muse, mutect2, varscan2
- UGT2B15 | c.480A>G p.L160= | Silent (SNP) | VAF 308/869 reads (35%) | catalogued as rs1395707077, COSV100592369; called by muse, mutect2, varscan2
- USH2A | c.9816G>A p.P3272= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as rs745566865, COSV56370507, COSV56420740; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP51 | c.1743A>G p.K581= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV72351422; called by muse, mutect2, varscan2
- USP51 | c.1134C>T p.V378= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as COSV101540678; called by muse, mutect2, varscan2
- VWA3B | c.774C>A p.A258= | Silent (SNP) | VAF 95/293 reads (32%) | catalogued as COSV68242354; called by muse, mutect2, varscan2
- YIPF7 | c.804C>T p.A268= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV100274490, COSV100274554; called by muse, mutect2, varscan2
- ZNF189 | c.303T>C p.F101= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as COSV99407242; called by muse, mutect2, varscan2
- ZNF292 | c.4617T>C p.T1539= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100370650; called by muse, mutect2, varscan2
- ZNF337 | c.846T>C p.H282= | Silent (SNP) | VAF 102/443 reads (23%) | catalogued as COSV53321054; called by muse, mutect2, varscan2
- ZNF544 | c.1638A>G p.K546= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV54135527; called by muse, varscan2
- ZNF546 | c.1626A>G p.R542= | Silent (SNP) | VAF 58/177 reads (33%) | catalogued as COSV100713497; called by muse, mutect2, varscan2
- ZNF649 | c.399T>C p.N133= | Silent (SNP) | VAF 95/300 reads (32%) | catalogued as COSV56815177; called by muse, mutect2, varscan2
- ZNF821 | c.798T>C p.P266= (on ENST00000425432 / NM_001376297.1; = p.P224= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV100546821; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-888T>C | Intron (SNP) | VAF 16/200 reads (8%) | catalogued as COSV100760400; called by muse, mutect2
- BTN2A3P | n.1559G>A | RNA (SNP) | VAF 59/188 reads (31%) | catalogued as rs1166084875; called by muse, mutect2, varscan2
- DCHS2 | n.3951G>A | RNA (SNP) | VAF 49/146 reads (34%) | catalogued as rs759769096, COSV100601557, COSV61767998, COSV61774246; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888371 ins GT | 3'Flank (INS) | VAF 65/296 reads (22%) | called by mutect2, varscan2
- LARP6 | c.200+2249A>G | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as rs759180458, COSV100150916; called by muse, mutect2, varscan2
- MGAM | c.4618+10782C>A | Intron (SNP) | VAF 74/107 reads (69%) | catalogued as COSV101527572; called by muse, mutect2, varscan2
- PARGP1 | n.256C>T | RNA (SNP) | VAF 64/200 reads (32%) | called by muse, mutect2, varscan2
- RAB28 | c.574-1253T>C | Intron (SNP) | VAF 33/225 reads (15%) | catalogued as COSV99986309; called by muse, mutect2, varscan2
- SLC35A3 | c.*668del | 3'UTR (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- TAOK2 | chr16:29991145 A>G | 3'Flank (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99663154; called by muse, mutect2, varscan2
- ZNF658B | n.1545A>T | RNA (SNP) | VAF 47/217 reads (22%) | called by muse, mutect2, varscan2
